Somatic mutation profile of tumor specimen TCGA-DB-5276-01A (aliquot TCGA-DB-5276-01A-01D-1468-08) from TCGA case TCGA-DB-5276, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 32.1 years (11,738 days).
Specimen TCGA-DB-5276-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3841860e-4fa1-4cd9-a01e-fecf29ff1a55.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-5276-10A (Blood Derived Normal), aliquot TCGA-DB-5276-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ce95629-26ab-44bb-8f4f-7d9d661094e8

The open-access MAF lists 15 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 8, Frame Shift Del 4, Silent 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 19/99 reads (19%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 22/52 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALMS1 | c.11139G>C p.Q3713H | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.106); catalogued as COSV52522059; called by muse, mutect2, varscan2
- BAIAP3 | c.2873dup p.H959Pfs*66 | Frame Shift Ins (INS) | VAF 12/70 reads (17%) | catalogued as rs1313326417; called by mutect2, pindel
- C12orf40 | c.1791_1794del p.T598Rfs*5 | Frame Shift Del (DEL) | VAF 23/129 reads (18%) | catalogued as rs1308527014; called by mutect2, pindel, varscan2
- MRPL58 | c.513_515del p.E171del | In Frame Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs1227780671; called by pindel, varscan2
- OR51V1 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV58314025, COSV58316425; called by muse, mutect2
- PRDM11 | c.955C>T p.R319C (on ENST00000530656 / NM_001359633.1; = p.R285C on NM_001256695.1) | Missense Mutation (SNP) | VAF 19/323 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs554343280, COSV55438120; called by muse, mutect2
- TBX22 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM054867, COSV64785449, COSV64788211; called by muse, mutect2, varscan2
- WDR3 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150881258; called by muse, mutect2, varscan2
- XIRP2 | c.10034C>G p.A3345G (on ENST00000628543; = p.A3520G on NM_152381.6) | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54734064; called by muse, mutect2, varscan2
- ATRX | c.1564_1567del p.S522Qfs*39 | Frame Shift Del (DEL) | VAF 64/251 reads (25%) | called by pindel, varscan2
- BCOR | c.4140_4141del p.E1382Ifs*26 (on ENST00000378444 / NM_001123385.2; = p.E1348Ifs*26 on NM_017745.6) | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- CPEB4 | c.243_244del p.Q83Afs*26 | Frame Shift Del (DEL) | VAF 34/196 reads (17%) | called by mutect2, pindel, varscan2
- RBP3 | c.711C>T p.G237= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs782037930; called by muse, mutect2, varscan2
